Somatic mutation profile of tumor specimen ALCH-B35Z-TTP1-A (aliquot ALCH-B35Z-TTP1-A-1-0-D-A78R-36) from ALCHEMIST case ALCH-B35Z, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 76.8 years (28,052 days).
Specimen ALCH-B35Z-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dd565bc3-ad58-475e-8df4-c7775167514f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B35Z-NB1-A (Blood Derived Normal), aliquot ALCH-B35Z-NB1-A-1-0-D-A78R-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1ddbd04a-c709-4b40-8a3f-e5abc65b8dae

The open-access MAF lists 271 somatic variants for this specimen: 190 protein-altering or splice-affecting, 41 silent, 40 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 158, Silent 41, Intron 18, Nonsense Mutation 12, 3'UTR 11, Frame Shift Del 9, 5'UTR 6, Splice Site 6, Frame Shift Ins 3, RNA 2, 5'Flank 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.473G>T p.R158L | Missense Mutation (SNP) | VAF 353/416 reads (85%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs587782144, CM102353, CM165595, CM994513, COSV52676395, COSV52678258, COSV52680378, COSV53545833; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A1CF | c.1712C>T p.A571V (on ENST00000373993 / NM_138932.2; = p.A563V on NM_014576.4) | Missense Mutation (SNP) | VAF 77/205 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.055); catalogued as rs758582733; called by muse, mutect2, varscan2
- ADAMTS12 | c.943G>C p.E315Q | Missense Mutation (SNP) | VAF 103/265 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.794); catalogued as COSV61270343; called by muse, mutect2, varscan2
- AGO3 | c.1593G>A p.A531= | Splice Region (SNP) | VAF 18/48 reads (38%) | catalogued as COSV99869584; called by muse, mutect2
- ALCAM | c.1540A>G p.I514V | Missense Mutation (SNP) | VAF 56/215 reads (26%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as rs1397200769; called by muse, mutect2, varscan2
- ANKZF1 | c.167G>T p.S56I | Missense Mutation (SNP) | VAF 94/197 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.466); catalogued as rs780126594, COSV99850956; called by muse, mutect2, varscan2
- BRCA1 | c.5194-2A>T p.X1732_splice | Splice Site (SNP) | VAF 251/659 reads (38%) | catalogued as CS043785, CS125650; called by muse, mutect2, varscan2
- C2orf16 | c.4853C>A p.P1618H | Missense Mutation (SNP) | VAF 155/403 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.068); catalogued as COSV62678261; called by muse, mutect2, varscan2
- CEP152 | c.2984C>T p.A995V | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.329); catalogued as rs146955708; called by muse, mutect2, varscan2
- CFAP100 | c.1684del p.R562Gfs*37 | Frame Shift Del (DEL) | VAF 87/458 reads (19%) | catalogued as COSV100729108; called by mutect2, pindel, varscan2
- CHRND | c.571C>T p.R191C | Missense Mutation (SNP) | VAF 105/543 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.625); catalogued as rs778217557, COSV51318697; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL22A1 | c.4538G>T p.R1513L | Missense Mutation (SNP) | VAF 140/291 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.297); catalogued as rs200298766, COSV100278836, COSV57343458; called by muse, mutect2, varscan2
- CSE1L | c.2071C>T p.Q691* | Nonsense Mutation (SNP) | VAF 208/570 reads (36%) | catalogued as rs865797058; called by muse, mutect2, varscan2
- CSMD3 | c.2528C>T p.A843V (on ENST00000297405 / NM_001363185.1; = p.A739V on NM_052900.3) | Missense Mutation (SNP) | VAF 82/215 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1336806392; called by muse, mutect2, varscan2
- CTAGE1 | c.527T>C p.I176T | Missense Mutation (SNP) | VAF 147/364 reads (40%) | SIFT tolerated (0.97); PolyPhen benign (0.053); catalogued as rs750407061; called by muse, mutect2, varscan2
- DDX60 | c.3974G>A p.R1325H | Missense Mutation (SNP) | VAF 60/120 reads (50%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as COSV67095477; called by muse, mutect2, varscan2
- DNMT3A | c.1792C>T p.R598* | Nonsense Mutation (SNP) | VAF 313/857 reads (37%) | catalogued as rs568207978, COSV53039812; called by muse, mutect2, varscan2
- DYSF | c.2801C>T p.P934L | Missense Mutation (SNP) | VAF 58/158 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs150717638; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- E2F8 | c.628A>G p.K210E | Missense Mutation (SNP) | VAF 145/311 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV51463387; called by muse, mutect2, varscan2
- EPS8 | c.1664A>G p.D555G | Missense Mutation (SNP) | VAF 194/325 reads (60%) | SIFT deleterious (0.01); PolyPhen benign (0.07); catalogued as rs778043464; called by muse, mutect2, varscan2
- ESYT2 | c.2177G>T p.G726V (on ENST00000613624; = p.G650V on NM_020728.3) | Missense Mutation (SNP) | VAF 227/502 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV51751565; called by muse, mutect2, varscan2
- FAM186B | c.644T>C p.M215T | Missense Mutation (SNP) | VAF 57/132 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1162279072; called by muse, mutect2, varscan2
- FSHB | c.111C>A p.F37L | Missense Mutation (SNP) | VAF 83/311 reads (27%) | SIFT tolerated (0.32); PolyPhen benign (0.012); catalogued as COSV99569491; called by muse, mutect2, varscan2
- FUBP1 | c.1795G>T p.A599S | Missense Mutation (SNP) | VAF 178/337 reads (53%) | SIFT tolerated (0.23); PolyPhen benign (0.104); catalogued as rs1182831029; called by muse, mutect2, varscan2
- HEATR5B | c.1024C>T p.R342W | Missense Mutation (SNP) | VAF 150/379 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs757984204, COSV99250147; called by muse, mutect2, varscan2
- HGF | c.1245G>T p.W415C | Missense Mutation (SNP) | VAF 132/344 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55954800; called by muse, mutect2, varscan2
- IL16 | c.211C>A p.P71T | Missense Mutation (SNP) | VAF 63/208 reads (30%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.051); catalogued as rs1487746868; called by muse, mutect2, varscan2
- KDM6A | c.3717G>T p.W1239C | Missense Mutation (SNP) | VAF 83/101 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as CM1211998, COSV65036973; called by muse, mutect2, varscan2
- KIF3A | c.1706G>A p.R569K | Missense Mutation (SNP) | VAF 71/101 reads (70%) | SIFT tolerated (0.17); PolyPhen benign (0.219); catalogued as COSV66414297; called by muse, mutect2, varscan2
- KRT32 | c.1188C>G p.Y396* | Nonsense Mutation (SNP) | VAF 208/452 reads (46%) | catalogued as rs751687243; called by muse, mutect2, varscan2
- KRTAP21-2 | c.198C>A p.S66R | Missense Mutation (SNP) | VAF 193/268 reads (72%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.001); catalogued as rs147370832; called by muse, mutect2, varscan2
- LATS2 | c.1343G>T p.R448L | Missense Mutation (SNP) | VAF 184/211 reads (87%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as rs762484566; called by muse, mutect2, varscan2
- LCE6A | c.173G>A p.R58H | Missense Mutation (SNP) | VAF 195/223 reads (87%) | SIFT tolerated (0.11); PolyPhen benign (0.02); catalogued as rs766698961, COSV70391417; called by muse, mutect2, varscan2
- LRFN5 | c.758G>T p.R253L | Missense Mutation (SNP) | VAF 152/200 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53254064; called by muse, mutect2, varscan2
- MORC1 | c.2069G>A p.C690Y | Missense Mutation (SNP) | VAF 102/389 reads (26%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.007); catalogued as rs1475229498; called by muse, mutect2, varscan2
- MUC16 | c.26846G>C p.R8949T | Missense Mutation (SNP) | VAF 133/196 reads (68%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.079); catalogued as rs1181389785; called by muse, mutect2, varscan2
- MUC5B | c.15772G>A p.D5258N | Missense Mutation (SNP) | VAF 152/316 reads (48%) | SIFT tolerated (0.58); PolyPhen benign (0.012); catalogued as rs887682705; called by muse, mutect2, varscan2
- MYOM1 | c.1582A>G p.I528V | Missense Mutation (SNP) | VAF 67/179 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as rs753840556; called by muse, varscan2
- NCAM2 | c.545G>T p.G182V | Missense Mutation (SNP) | VAF 79/113 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53085504; called by muse, mutect2, varscan2
- NCLN | c.346A>G p.M116V | Missense Mutation (SNP) | VAF 86/109 reads (79%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs753775524; called by muse, mutect2, varscan2
- NFE2L3 | c.1843_1846del p.A615Rfs*18 | Frame Shift Del (DEL) | VAF 45/172 reads (26%) | catalogued as rs753571610; called by pindel, varscan2
- NLRP3 | c.350del p.G117Vfs*14 | Frame Shift Del (DEL) | VAF 570/913 reads (62%) | catalogued as COSV60231846; called by mutect2, pindel, varscan2
- NOTCH4 | c.4994G>A p.R1665Q | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as COSV66685303; called by muse, mutect2, varscan2
- NTRK3 | c.1989C>G p.I663M | Missense Mutation (SNP) | VAF 180/461 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62299328; called by muse, mutect2, varscan2
- NUP155 | c.1172G>T p.R391L (on ENST00000231498 / NM_153485.3; = p.R332L on NM_004298.4) | Missense Mutation (SNP) | VAF 117/317 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM086387; called by muse, mutect2, varscan2
- NUS1 | c.554A>G p.H185R | Missense Mutation (SNP) | VAF 66/246 reads (27%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs1474271739; called by muse, varscan2
- OR2M4 | c.319del p.L107Cfs*30 | Frame Shift Del (DEL) | VAF 384/594 reads (65%) | catalogued as COSV100141017; called by mutect2, pindel, varscan2
- OR4A15 | c.684G>T p.L228F | Missense Mutation (SNP) | VAF 49/239 reads (21%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.03); catalogued as rs756115731, COSV100124304, COSV59038052; called by muse, mutect2, varscan2
- PCDH15 | c.4949C>G p.S1650W | Missense Mutation (SNP) | VAF 142/408 reads (35%) | SIFT deleterious, low confidence (0.01); catalogued as rs183631592; called by muse, mutect2, varscan2
- PCDH15 | c.635del p.G212Efs*3 | Frame Shift Del (DEL) | VAF 128/375 reads (34%) | catalogued as COSV57348197; called by mutect2, pindel, varscan2
- PCLO | c.7097C>T p.T2366I | Missense Mutation (SNP) | VAF 68/178 reads (38%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as rs921577896; called by muse, mutect2, varscan2
- PLXND1 | c.2993G>A p.R998K | Missense Mutation (SNP) | VAF 71/152 reads (47%) | SIFT tolerated (0.51); PolyPhen benign (0.03); catalogued as rs1347781954; called by muse, mutect2, varscan2
- PMEPA1 | c.307G>A p.G103R | Missense Mutation (SNP) | VAF 128/734 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.855); catalogued as rs924182556, COSV55696564; called by muse, mutect2, varscan2
- POTEH | c.990G>T p.K330N | Missense Mutation (SNP) | VAF 179/1679 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.995); catalogued as COSV58885247; called by muse, mutect2, varscan2
- PPP4R3C | c.2401C>G p.P801A | Missense Mutation (SNP) | VAF 114/142 reads (80%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.495); catalogued as COSV69081150; called by muse, mutect2, varscan2
- PROKR2 | c.491G>A p.R164Q | Missense Mutation (SNP) | VAF 63/191 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751875578, CM065402, COSV54087267, COSV54087377; called by muse, mutect2, varscan2
- PZP | c.1720C>A p.P574T | Missense Mutation (SNP) | VAF 133/447 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.023); catalogued as COSV54367088; called by muse, mutect2, varscan2
- RELT | c.31T>A p.S11T | Missense Mutation (SNP) | VAF 74/148 reads (50%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as COSV99293056; called by muse, mutect2, varscan2
- ROR2 | c.2288G>A p.G763E | Missense Mutation (SNP) | VAF 622/756 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65222884; called by muse, mutect2, varscan2
- SCN2A | c.2908G>A p.G970R | Missense Mutation (SNP) | VAF 14/412 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.11); catalogued as COSV51840010; called by muse, mutect2
- SLC26A6 | c.169C>T p.R57W | Missense Mutation (SNP) | VAF 78/216 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs776632960; called by muse, mutect2, varscan2
- SLC35B2 | c.1291_1293del p.K431del | In Frame Del (DEL) | VAF 11/50 reads (22%) | catalogued as rs752392556; called by mutect2, pindel
- SLC7A7 | c.1366T>A p.F456I | Missense Mutation (SNP) | VAF 222/326 reads (68%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as COSV53537022, COSV53538722; called by muse, mutect2, varscan2
- SSTR3 | c.767C>A p.T256K | Missense Mutation (SNP) | VAF 201/480 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370263249; called by muse, mutect2, varscan2
- TCF21 | c.265C>T p.R89W | Missense Mutation (SNP) | VAF 217/469 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52818022, COSV99399487; called by muse, mutect2, varscan2
- TMC2 | c.521C>T p.P174L | Missense Mutation (SNP) | VAF 102/270 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100727529; called by muse, mutect2, varscan2
- TMC3 | c.2114G>C p.R705P | Missense Mutation (SNP) | VAF 165/429 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100845809; called by muse, mutect2, varscan2
- TMEM145 | c.242A>G p.Q81R | Missense Mutation (SNP) | VAF 175/233 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs771493201; called by muse, mutect2, varscan2
- TTC3 | c.4847A>T p.K1616I | Missense Mutation (SNP) | VAF 39/48 reads (81%) | SIFT deleterious (0); PolyPhen possibly damaging (0.603); catalogued as COSV61290007; called by muse, mutect2, varscan2
- XPO1 | c.1268G>C p.R423P | Missense Mutation (SNP) | VAF 70/137 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV68947626; called by muse, mutect2, varscan2
- ZBTB49 | c.2162A>G p.N721S | Missense Mutation (SNP) | VAF 190/357 reads (53%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as rs536676774; called by muse, mutect2, varscan2
- ZBTB7C | c.130G>T p.E44* | Nonsense Mutation (SNP) | VAF 147/387 reads (38%) | catalogued as COSV59689145, COSV59690488; called by muse, mutect2, varscan2
- ZRANB2 | c.757G>T p.G253W | Missense Mutation (SNP) | VAF 93/191 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as COSV54672883; called by muse, mutect2, varscan2
- ACVR1C | c.390G>T p.M130I | Missense Mutation (SNP) | VAF 176/591 reads (30%) | SIFT tolerated (0.94); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ADCY8 | c.2843A>T p.E948V | Missense Mutation (SNP) | VAF 352/656 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- ADGRG4 | c.6479C>A p.P2160Q | Missense Mutation (SNP) | VAF 124/157 reads (79%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- AHNAK | c.500G>T p.R167L | Missense Mutation (SNP) | VAF 96/196 reads (49%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- AJUBA | c.1120_1121dup p.C375Vfs*36 | Frame Shift Ins (INS) | VAF 22/46 reads (48%) | called by mutect2, pindel, varscan2
- ANKRD20A1 | c.564G>T p.K188N | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0.001); called by mutect2, varscan2
- ANO3 | c.1479A>T p.R493S | Missense Mutation (SNP) | VAF 51/227 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); called by muse, mutect2, varscan2
- AP001781.2 | c.232G>A p.E78K | Missense Mutation (SNP) | VAF 11/266 reads (4%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0); called by muse, mutect2
- ATP6V0A4 | c.748C>T p.P250S | Missense Mutation (SNP) | VAF 233/591 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.589); called by muse, mutect2, varscan2
- BACH1 | c.1702A>T p.R568* | Nonsense Mutation (SNP) | VAF 39/57 reads (68%) | called by muse, mutect2, varscan2
- BRD7 | c.208G>T p.E70* | Nonsense Mutation (SNP) | VAF 310/969 reads (32%) | called by muse, mutect2, varscan2
- C10orf71 | c.257C>A p.P86Q | Missense Mutation (SNP) | VAF 58/115 reads (50%) | SIFT tolerated (0.09); PolyPhen benign (0.389); called by muse, mutect2, varscan2
- C1orf167 | c.2867G>C p.W956S | Missense Mutation (SNP) | VAF 94/134 reads (70%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.472); called by muse, mutect2, varscan2
- CAND1 | c.300A>T p.E100D | Missense Mutation (SNP) | VAF 80/172 reads (47%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.89); called by muse, mutect2, varscan2
- CHCHD7 | c.242del p.G81Efs*10 (on ENST00000355315 / NM_001011671.3; = p.G93Efs*10 on NM_024300.4) | Frame Shift Del (DEL) | VAF 81/251 reads (32%) | called by mutect2, pindel, varscan2
- CNTNAP4 | c.1913G>T p.G638V | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- COG2 | c.1191A>T p.L397F | Missense Mutation (SNP) | VAF 389/489 reads (80%) | SIFT tolerated (0.22); PolyPhen benign (0.18); called by muse, mutect2, varscan2
- COG4 | c.434G>A p.G145E | Missense Mutation (SNP) | VAF 199/560 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- CRISP2 | c.143G>T p.R48M | Missense Mutation (SNP) | VAF 182/485 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EDNRB | c.890G>C p.S297T (on ENST00000377211 / NM_001201397.1; = p.S207T on NM_000115.5) | Missense Mutation (SNP) | VAF 252/303 reads (83%) | SIFT tolerated (0.14); PolyPhen benign (0.329); called by muse, mutect2, varscan2
- EFHC1 | c.341A>C p.Q114P | Missense Mutation (SNP) | VAF 94/256 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ERF | c.688G>C p.G230R | Missense Mutation (SNP) | VAF 96/119 reads (81%) | SIFT tolerated (0.11); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- ERI3 | c.119G>C p.W40S | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); called by muse, varscan2
- EVI5 | c.1829G>A p.S610N | Missense Mutation (SNP) | VAF 136/334 reads (41%) | SIFT tolerated (0.54); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FAM184B | c.690G>T p.E230D | Missense Mutation (SNP) | VAF 99/419 reads (24%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.493); called by muse, mutect2, varscan2
- FAM90A26 | c.769C>T p.Q257* | Nonsense Mutation (SNP) | VAF 317/462 reads (69%) | called by muse, mutect2, varscan2
- FLNC | c.5525G>A p.G1842D | Missense Mutation (SNP) | VAF 154/420 reads (37%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- FRMPD2 | c.281G>T p.S94I | Missense Mutation (SNP) | VAF 75/169 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- FSIP2 | c.315A>C p.L105F | Missense Mutation (SNP) | VAF 64/167 reads (38%) | SIFT deleterious (0); called by muse, mutect2
- FSIP2 | c.317A>T p.K106I | Missense Mutation (SNP) | VAF 64/169 reads (38%) | SIFT deleterious (0); called by muse, mutect2
- GAD2 | c.595A>G p.T199A | Missense Mutation (SNP) | VAF 110/286 reads (38%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- GLB1L | c.1043T>A p.L348H | Missense Mutation (SNP) | VAF 64/135 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- GOLGA8J | c.694C>A p.Q232K | Missense Mutation (SNP) | VAF 235/340 reads (69%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- GOLM2 | c.604G>A p.D202N | Missense Mutation (SNP) | VAF 77/167 reads (46%) | SIFT tolerated (0.17); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- GRB10 | c.1545-1G>T p.X515_splice (on ENST00000398812; = p.X469_splice on NM_001001549.3) | Splice Site (SNP) | VAF 215/576 reads (37%) | called by muse, mutect2, varscan2
- GRM1 | c.3559T>A p.Y1187N | Missense Mutation (SNP) | VAF 406/1049 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- GSDMD | c.1332G>C p.E444D | Missense Mutation (SNP) | VAF 172/576 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.767); called by muse, mutect2, varscan2
- HTR1A | c.895G>T p.G299C | Missense Mutation (SNP) | VAF 85/136 reads (63%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- IBTK | c.1116G>T p.M372I | Missense Mutation (SNP) | VAF 37/93 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- IGHV1OR15-9 | c.79G>T p.G27W | Missense Mutation (SNP) | VAF 118/379 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- INSC | c.763A>T p.T255S | Missense Mutation (SNP) | VAF 86/388 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- IRF6 | c.1103dup p.F369Vfs*2 | Frame Shift Ins (INS) | VAF 404/658 reads (61%) | called by mutect2, pindel, varscan2
- ITIH2 | c.1971C>G p.Y657* | Nonsense Mutation (SNP) | VAF 85/441 reads (19%) | called by muse, mutect2, varscan2
- ITIH6 | c.3606del p.Y1204Tfs*5 | Frame Shift Del (DEL) | VAF 125/204 reads (61%) | called by mutect2, pindel, varscan2
- JMJD1C | c.775A>G p.T259A | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- KALRN | c.2164A>T p.R722W | Missense Mutation (SNP) | VAF 188/368 reads (51%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KCNK13 | c.179T>C p.F60S | Missense Mutation (SNP) | VAF 80/117 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- KCNMA1 | c.2902+1G>T p.X968_splice (on ENST00000286628 / NM_001161352.2; = p.X910_splice on NM_002247.4) | Splice Site (SNP) | VAF 124/350 reads (35%) | called by muse, mutect2, varscan2
- KIF1B | c.4064A>T p.Y1355F (on ENST00000377086 / NM_001365952.1; = p.Y1309F on NM_015074.3) | Missense Mutation (SNP) | VAF 227/789 reads (29%) | SIFT tolerated (0.42); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KIF2B | c.744G>T p.E248D | Missense Mutation (SNP) | VAF 148/433 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- KLHL4 | c.1785C>G p.N595K | Missense Mutation (SNP) | VAF 87/110 reads (79%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- KMT2D | c.5994_6001dup p.R2001Lfs*49 | Frame Shift Ins (INS) | VAF 166/484 reads (34%) | called by mutect2, varscan2
- KRTAP13-3 | c.130A>G p.S44G | Missense Mutation (SNP) | VAF 164/243 reads (67%) | SIFT deleterious (0.03); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- LCE1B | c.96G>C p.K32N | Missense Mutation (SNP) | VAF 433/893 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.624); called by muse, mutect2, varscan2
- LYVE1 | c.536C>A p.P179H | Missense Mutation (SNP) | VAF 89/355 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MAN2A1 | c.1163del p.P388Qfs*17 | Frame Shift Del (DEL) | VAF 64/131 reads (49%) | called by mutect2, pindel, varscan2
- MAP1A | c.4618_4619del p.K1540Gfs*2 | Frame Shift Del (DEL) | VAF 50/185 reads (27%) | called by mutect2, pindel, varscan2
- MDGA2 | c.420+1G>A p.X140_splice | Splice Site (SNP) | VAF 76/99 reads (77%) | called by muse, mutect2, varscan2
- MEAK7 | c.824A>T p.H275L | Missense Mutation (SNP) | VAF 148/352 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- MED13 | c.3185T>G p.V1062G | Missense Mutation (SNP) | VAF 121/329 reads (37%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- MGAM2 | c.2482T>A p.S828T | Missense Mutation (SNP) | VAF 37/87 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.634); called by muse, mutect2, varscan2
- MGMT | c.640G>T p.G214W (on ENST00000306010; = p.G183W on NM_002412.5) | Missense Mutation (SNP) | VAF 148/369 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- MRC2 | c.3860G>A p.G1287D | Missense Mutation (SNP) | VAF 80/204 reads (39%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- MUC5AC | c.338C>T p.A113V | Missense Mutation (SNP) | VAF 395/705 reads (56%) | SIFT deleterious (0.04); called by muse, mutect2, varscan2
- MUC5AC | c.614A>G p.N205S | Missense Mutation (SNP) | VAF 57/550 reads (10%) | SIFT deleterious (0); called by muse, mutect2
- MYH7B | c.2571T>A p.D857E | Missense Mutation (SNP) | VAF 60/150 reads (40%) | SIFT tolerated (0.71); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- NRK | c.3358G>C p.A1120P | Missense Mutation (SNP) | VAF 87/102 reads (85%) | SIFT tolerated (0.09); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- OR4A15 | c.685G>T p.E229* | Nonsense Mutation (SNP) | VAF 49/232 reads (21%) | called by muse, mutect2, varscan2
- OR7A17 | c.719C>T p.T240I | Missense Mutation (SNP) | VAF 125/166 reads (75%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- OR8B12 | c.401C>G p.T134S | Missense Mutation (SNP) | VAF 61/109 reads (56%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- OTUD4 | c.295-2A>T p.X99_splice (on ENST00000447906 / NM_001366057.1; = p.X34_splice on NM_017493.7 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 24/107 reads (22%) | called by muse, mutect2, varscan2
- PAN2 | c.3327G>T p.M1109I (on ENST00000425394 / NM_001127460.3; = p.M1105I on NM_014871.5) | Missense Mutation (SNP) | VAF 47/271 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PCDH1 | c.2887C>T p.P963S | Missense Mutation (SNP) | VAF 11/14 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PIEZO2 | c.5466C>A p.D1822E | Missense Mutation (SNP) | VAF 160/399 reads (40%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.747); called by muse, mutect2, varscan2
- PLXND1 | c.2243G>A p.S748N | Missense Mutation (SNP) | VAF 70/211 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- POLDIP3 | c.373A>G p.R125G | Missense Mutation (SNP) | VAF 72/209 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- POTEB3 | c.1193C>A p.P398Q | Missense Mutation (SNP) | VAF 117/722 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- POTEH | c.478T>C p.Y160H | Missense Mutation (SNP) | VAF 456/2187 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.006); called by muse, varscan2
- PPM1D | c.479G>T p.W160L | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PPM1D | c.480G>T p.W160C | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PRSS36 | c.501C>A p.F167L | Missense Mutation (SNP) | VAF 261/717 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.34); called by muse, mutect2, varscan2
- PSMA8 | c.605C>A p.A202D | Missense Mutation (SNP) | VAF 85/194 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- PTBP2 | c.1365T>G p.F455L (on ENST00000426398 / NM_001300986.2; = p.F447L on NM_021190.4) | Missense Mutation (SNP) | VAF 79/292 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- PTPRZ1 | c.2103G>T p.Q701H | Missense Mutation (SNP) | VAF 125/331 reads (38%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- RARG | c.565C>A p.L189I | Missense Mutation (SNP) | VAF 28/142 reads (20%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.562); called by muse, mutect2, varscan2
- RASA1 | c.1610+1G>A p.X537_splice | Splice Site (SNP) | VAF 180/264 reads (68%) | called by muse, mutect2, varscan2
- RBMXL3 | c.2758T>A p.S920T | Missense Mutation (SNP) | VAF 193/231 reads (84%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.483); called by muse, mutect2, varscan2
- RHCE | c.655T>C p.F219L | Missense Mutation (SNP) | VAF 194/301 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- RYR2 | c.13862C>T p.P4621L | Missense Mutation (SNP) | VAF 291/348 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SEC14L6 | c.931G>A p.G311S | Missense Mutation (SNP) | VAF 79/189 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- SI | c.5396A>G p.N1799S | Missense Mutation (SNP) | VAF 67/204 reads (33%) | SIFT tolerated (0.95); PolyPhen benign (0); called by muse, mutect2, varscan2
- SI | c.4672C>A p.H1558N | Missense Mutation (SNP) | VAF 102/373 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SIGLEC1 | c.4339G>T p.V1447L | Missense Mutation (SNP) | VAF 100/208 reads (48%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.925); called by muse, varscan2
- SKOR2 | c.1205G>T p.G402V | Missense Mutation (SNP) | VAF 47/95 reads (49%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- SLCO1A2 | c.484C>A p.L162I | Missense Mutation (SNP) | VAF 136/265 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.612); called by muse, mutect2, varscan2
- SMIM12 | c.25G>A p.V9I | Missense Mutation (SNP) | VAF 66/125 reads (53%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- STRN | c.1629G>A p.W543* | Nonsense Mutation (SNP) | VAF 149/401 reads (37%) | called by muse, mutect2, varscan2
- TAAR2 | c.430G>T p.A144S (on ENST00000367931 / NM_001033080.1; = p.A99S on NM_014626.3) | Missense Mutation (SNP) | VAF 80/218 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- TBCD | c.709G>T p.A237S | Missense Mutation (SNP) | VAF 159/414 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TENM1 | c.181A>T p.S61C | Missense Mutation (SNP) | VAF 117/138 reads (85%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.529); called by muse, mutect2, varscan2
- TM4SF18 | c.407G>T p.G136V | Missense Mutation (SNP) | VAF 168/329 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.231); called by muse, mutect2, varscan2
- TMEM132C | c.1894C>A p.L632M | Missense Mutation (SNP) | VAF 90/353 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TRBV7-1 | c.298C>G p.R100G | Missense Mutation (SNP) | VAF 75/192 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- TRPS1 | c.1971G>T p.Q657H (on ENST00000220888 / NM_001330599.2; = p.Q670H on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 138/324 reads (43%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- TTC34 | c.3151G>T p.G1051C | Missense Mutation (SNP) | VAF 201/666 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TTLL13P | c.2053G>A p.A685T | Missense Mutation (SNP) | VAF 30/516 reads (6%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.106); called by muse, mutect2
- TTN | c.54757T>C p.C18253R (on ENST00000591111; = p.C10829R on NM_003319.4) | Missense Mutation (SNP) | VAF 18/372 reads (5%) | PolyPhen possibly damaging (0.775); called by muse, mutect2
- TTN | c.36499C>G p.R12167G (on ENST00000591111; = p.R4743G on NM_003319.4) | Missense Mutation (SNP) | VAF 19/101 reads (19%) | PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- TTN | c.8731C>G p.P2911A (on ENST00000591111; = p.P2865A on NM_003319.4) | Missense Mutation (SNP) | VAF 127/236 reads (54%) | PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TTN | c.199A>T p.I67F | Missense Mutation (SNP) | VAF 216/409 reads (53%) | PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- WDR88 | c.600C>A p.Y200* | Nonsense Mutation (SNP) | VAF 155/224 reads (69%) | called by muse, mutect2, varscan2
- ZBTB25 | c.317A>T p.Y106F | Missense Mutation (SNP) | VAF 129/214 reads (60%) | SIFT tolerated (0.42); PolyPhen benign (0.339); called by muse, mutect2, varscan2
- ZNF235 | c.2050A>G p.T684A | Missense Mutation (SNP) | VAF 161/198 reads (81%) | SIFT deleterious (0.01); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- ZNF644 | c.314G>C p.S105T | Missense Mutation (SNP) | VAF 120/279 reads (43%) | SIFT tolerated (0.37); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZNHIT6 | c.1345A>C p.N449H | Missense Mutation (SNP) | VAF 78/260 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- ZSCAN10 | c.1972G>T p.A658S (on ENST00000252463; = p.A713S on NM_032805.3) | Missense Mutation (SNP) | VAF 76/192 reads (40%) | SIFT tolerated (0.42); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- ZSCAN10 | c.931C>T p.Q311* (on ENST00000252463; = p.Q366* on NM_032805.3) | Nonsense Mutation (SNP) | VAF 127/298 reads (43%) | called by muse, mutect2, varscan2
- ALK | c.1692G>T p.V564= | Silent (SNP) | VAF 230/588 reads (39%) | catalogued as COSV66583060; called by muse, varscan2
- AVL9 | c.1008T>C p.P336= | Silent (SNP) | VAF 58/188 reads (31%) | called by muse, mutect2, varscan2
- BOC | c.2607C>T p.I869= | Silent (SNP) | VAF 174/647 reads (27%) | catalogued as rs777764638; called by muse, mutect2, varscan2
- C2CD5 | c.2481A>G p.P827= | Silent (SNP) | VAF 66/324 reads (20%) | called by muse, mutect2, varscan2
- CAPG | c.726C>T p.D242= | Silent (SNP) | VAF 242/538 reads (45%) | catalogued as rs1285568961; called by muse, mutect2, varscan2
- CASP10 | c.1548G>A p.R516= | Silent (SNP) | VAF 211/369 reads (57%) | catalogued as rs767152226, COSV51859339; called by muse, mutect2, varscan2
- CCDC141 | c.4110G>C p.S1370= | Silent (SNP) | VAF 123/232 reads (53%) | catalogued as rs536436075, COSV55378965; called by muse, mutect2, varscan2
- CCDC57 | c.1668G>A p.A556= | Silent (SNP) | VAF 412/1064 reads (39%) | catalogued as rs559681820; called by muse, mutect2, varscan2
- CDH22 | c.429C>G p.A143= | Silent (SNP) | VAF 345/996 reads (35%) | called by muse, mutect2, varscan2
- COL20A1 | c.2578C>A p.R860= | Silent (SNP) | VAF 128/306 reads (42%) | called by muse, mutect2, varscan2
- CPNE2 | c.237C>T p.F79= | Silent (SNP) | VAF 134/324 reads (41%) | catalogued as rs193160367; called by muse, mutect2, varscan2
- CREBBP | c.2763A>T p.A921= | Silent (SNP) | VAF 121/321 reads (38%) | called by muse, mutect2, varscan2
- EYA3 | c.1245A>T p.L415= | Silent (SNP) | VAF 122/167 reads (73%) | called by muse, mutect2, varscan2
- F2RL1 | c.927G>T p.V309= | Silent (SNP) | VAF 103/149 reads (69%) | called by muse, mutect2, varscan2
- FEZ1 | c.330A>T p.T110= | Silent (SNP) | VAF 86/364 reads (24%) | called by muse, mutect2, varscan2
- GREB1L | c.1350G>T p.V450= | Silent (SNP) | VAF 107/244 reads (44%) | called by muse, mutect2, varscan2
- HCAR2 | c.825G>A p.A275= | Silent (SNP) | VAF 165/590 reads (28%) | catalogued as rs202067823, COSV61024215; called by muse, mutect2, varscan2
- HSPG2 | c.2664C>T p.S888= | Silent (SNP) | VAF 239/325 reads (74%) | catalogued as rs560919408; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KIAA2013 | c.316C>A p.R106= | Silent (SNP) | VAF 332/609 reads (55%) | called by muse, mutect2, varscan2
- KLHL33 | c.1161G>T p.L387= | Silent (SNP) | VAF 231/586 reads (39%) | catalogued as COSV60725201; called by muse, mutect2, varscan2
- KRBA1 | c.2775G>A p.G925= | Silent (SNP) | VAF 138/380 reads (36%) | called by muse, mutect2, varscan2
- LRP1 | c.10425G>C p.R3475= | Silent (SNP) | VAF 38/152 reads (25%) | called by muse, mutect2, varscan2
- LRP5 | c.966C>T p.A322= | Silent (SNP) | VAF 104/404 reads (26%) | called by muse, mutect2, varscan2
- MCF2L2 | c.385T>C p.L129= | Silent (SNP) | VAF 22/76 reads (29%) | catalogued as rs1167556077, COSV61053647; called by muse, mutect2, varscan2
- METTL3 | c.1539A>G p.K513= | Silent (SNP) | VAF 190/338 reads (56%) | called by muse, mutect2, varscan2
- MMRN1 | c.3564T>A p.T1188= | Silent (SNP) | VAF 24/302 reads (8%) | called by muse, mutect2
- MSX2 | c.177C>A p.P59= | Silent (SNP) | VAF 281/386 reads (73%) | called by muse, mutect2, varscan2
- OR10S1 | c.936T>C p.A312= | Silent (SNP) | VAF 37/143 reads (26%) | called by muse, mutect2, varscan2
- OR2B11 | c.642C>G p.P214= | Silent (SNP) | VAF 388/475 reads (82%) | catalogued as COSV59509826; called by muse, mutect2, varscan2
- OR2M5 | c.747A>T p.G249= | Silent (SNP) | VAF 491/597 reads (82%) | called by muse, mutect2, varscan2
- PREX1 | c.4446C>A p.G1482= | Silent (SNP) | VAF 280/698 reads (40%) | called by muse, mutect2, varscan2
- RASA2 | c.39C>G p.S13= | Silent (SNP) | VAF 145/490 reads (30%) | called by muse, mutect2, varscan2
- RPS6KA2 | c.1413C>T p.T471= | Silent (SNP) | VAF 71/193 reads (37%) | catalogued as rs781510495; called by muse, mutect2, varscan2
- SDK2 | c.2259G>A p.L753= | Silent (SNP) | VAF 105/342 reads (31%) | called by muse, mutect2, varscan2
- SERPINA10 | c.258G>A p.L86= | Silent (SNP) | VAF 255/385 reads (66%) | called by muse, mutect2, varscan2
- SLC4A10 | c.2580T>A p.A860= (on ENST00000446997 / NM_001354461.2; = p.A830= on NM_022058.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 235/439 reads (54%) | called by muse, mutect2, varscan2
- SVIL | c.6591C>T p.N2197= (on ENST00000355867 / NM_021738.3; = p.N1771= on NM_003174.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 42/196 reads (21%) | catalogued as rs531901887; called by muse, mutect2
- TTN | c.15678C>A p.A5226= (on ENST00000591111; = p.A4299= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 5/20 reads (25%) | called by muse, mutect2, varscan2
- UNC93A | c.876C>A p.V292= | Silent (SNP) | VAF 196/513 reads (38%) | called by muse, mutect2, varscan2
- XDH | c.108G>C p.L36= | Silent (SNP) | VAF 83/211 reads (39%) | called by muse, mutect2, varscan2
- ZNF195 | c.420G>A p.E140= | Silent (SNP) | VAF 28/124 reads (23%) | catalogued as rs1365927524; called by muse, mutect2, varscan2
- ACAA2 | chr18:49814196 ins A | 5'Flank (INS) | VAF 168/503 reads (33%) | called by mutect2, pindel, varscan2
- ADM2 | c.*191_*221del | 3'UTR (DEL) | VAF 164/406 reads (40%) | called by mutect2, pindel
- AL353804.4 | chrX:73823606 G>A | 5'Flank (SNP) | VAF 141/171 reads (82%) | called by muse, mutect2, varscan2
- AP000356.3 | chr22:24650822 C>T | 3'Flank (SNP) | VAF 142/393 reads (36%) | catalogued as rs1395288690; called by muse, mutect2, varscan2
- ARPP21 | c.2032+573C>G | Intron (SNP) | VAF 47/83 reads (57%) | catalogued as COSV99490974; called by muse, mutect2, varscan2
- C1QB | c.*46G>A | 3'UTR (SNP) | VAF 106/142 reads (75%) | catalogued as rs768173375; called by muse, mutect2, varscan2
- CFAP46 | c.7117+592G>T | Intron (SNP) | VAF 112/333 reads (34%) | called by muse, mutect2, varscan2
- CIB3 | c.*18C>A | 3'UTR (SNP) | VAF 176/229 reads (77%) | catalogued as rs759646559; called by muse, mutect2, varscan2
- CXCL12 | c.*380G>A | 3'UTR (SNP) | VAF 267/677 reads (39%) | called by muse, mutect2, varscan2
- DAG1 | c.*238del | 3'UTR (DEL) | VAF 112/209 reads (54%) | called by mutect2, pindel, varscan2
- DNAH7 | c.1353+1537T>C | Intron (SNP) | VAF 93/189 reads (49%) | called by muse, mutect2, varscan2
- EIF3L | c.293+20A>G | Intron (SNP) | VAF 79/195 reads (41%) | catalogued as rs1367322392; called by muse, mutect2, varscan2
- ETV3 | c.-7G>A | 5'UTR (SNP) | VAF 116/141 reads (82%) | called by muse, mutect2, varscan2
- EXD1 | c.29-2717T>A | Intron (SNP) | VAF 103/361 reads (29%) | called by muse, mutect2, varscan2
- FZD4 | c.*37G>C | 3'UTR (SNP) | VAF 63/139 reads (45%) | called by muse, mutect2, varscan2
- GDAP1 | c.*1949G>T | 3'UTR (SNP) | VAF 82/206 reads (40%) | called by muse, mutect2, varscan2
- HILPDA | c.-208T>A | 5'UTR (SNP) | VAF 219/512 reads (43%) | called by muse, mutect2, varscan2
- IGFN1 | c.1241+3390G>C | Intron (SNP) | VAF 478/595 reads (80%) | called by muse, varscan2
- IMPDH1 | c.325-17A>T | Intron (SNP) | VAF 156/392 reads (40%) | called by muse, mutect2, varscan2
- KIRREL3 | c.56-118876A>G | Intron (SNP) | VAF 20/38 reads (53%) | called by muse, varscan2
- LRCH4 | c.1855-108G>T | Intron (SNP) | VAF 19/43 reads (44%) | called by muse, mutect2, varscan2
- MARCHF1 | c.-322-85678G>A | Intron (SNP) | VAF 97/424 reads (23%) | called by muse, mutect2, varscan2
- MED13L | c.-35A>T | 5'UTR (SNP) | VAF 428/715 reads (60%) | called by muse, mutect2, varscan2
- MED13L | c.-36C>A | 5'UTR (SNP) | VAF 421/697 reads (60%) | called by muse, mutect2, varscan2
- NAMPTP1 | n.965A>T | RNA (SNP) | VAF 187/516 reads (36%) | called by muse, mutect2, varscan2
- NTF3 | c.*48A>T | 3'UTR (SNP) | VAF 61/262 reads (23%) | called by muse, mutect2, varscan2
- NXF1 | c.1821+9T>C | Intron (SNP) | VAF 21/231 reads (9%) | called by muse, mutect2
- OSBPL6 | c.*178T>A | 3'UTR (SNP) | VAF 19/84 reads (23%) | called by muse, mutect2, varscan2
- PADI4 | c.340+485A>G | Intron (SNP) | VAF 7/113 reads (6%) | catalogued as rs1036598090; called by muse, mutect2
- PCDHB13 | c.*105C>T | 3'UTR (SNP) | VAF 117/157 reads (75%) | catalogued as rs782261509, COSV53396666; called by muse, mutect2, varscan2
- PLA2R1 | c.-17G>C | 5'UTR (SNP) | VAF 210/532 reads (39%) | catalogued as rs977477983, COSV51778354; called by muse, varscan2
- PPP1R13B | c.*563C>T | 3'UTR (SNP) | VAF 402/563 reads (71%) | catalogued as rs933007843; called by muse, mutect2, varscan2
- RBM12B | c.-78+416G>C | Intron (SNP) | VAF 267/665 reads (40%) | called by muse, mutect2, varscan2
- SLC7A9 | c.750-47G>T | Intron (SNP) | VAF 310/415 reads (75%) | called by muse, mutect2, varscan2
- SLC7A9 | c.750-48G>T | Intron (SNP) | VAF 312/418 reads (75%) | called by muse, mutect2, varscan2
- STAB1 | c.2235+152C>A | Intron (SNP) | VAF 99/124 reads (80%) | called by muse, mutect2, varscan2
- TEX49 | c.79+8585C>A | Intron (SNP) | VAF 34/165 reads (21%) | called by muse, mutect2, varscan2
- TPRX1 | c.-149C>T | 5'UTR (SNP) | VAF 23/28 reads (82%) | called by mutect2, varscan2
- YY1AP1 | c.47+58A>G | Intron (SNP) | VAF 26/566 reads (5%) | called by muse, mutect2
- ZNF849P | n.1225G>A | RNA (SNP) | VAF 212/378 reads (56%) | called by muse, varscan2
